Somatic mutation profile of tumor specimen TCGA-FS-A1ZN-01A (aliquot TCGA-FS-A1ZN-01A-11D-A197-08) from TCGA case TCGA-FS-A1ZN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 43.5 years (15,890 days).
Specimen TCGA-FS-A1ZN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1dbb803-5f5b-42b3-b60f-3762b8e4e793.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZN-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZN-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/288cb794-b344-4112-8622-a647011d7f77

The open-access MAF lists 116 somatic variants for this specimen: 78 protein-altering or splice-affecting, 35 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 35, Nonsense Mutation 8, RNA 1, Splice Site 1, Splice Region 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3R1 | c.1425+2T>G p.X475_splice (on ENST00000521381 / NM_181523.3; = p.X205_splice on NM_181504.4) | Splice Site (SNP) | VAF 26/77 reads (34%) | hotspot (GDC flag); catalogued as rs1554051075, CS165034, COSV57135132, COSV57139824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCD3 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 90/194 reads (46%) | catalogued as COSV64643883; called by muse, mutect2, varscan2
- ADGRF4 | c.1298C>T p.T433M | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs146828294, COSV51951121; called by mutect2, varscan2
- AL592490.1 | c.2749G>A p.E917K | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868417297, COSV69427161; called by muse, mutect2, varscan2
- ANKS1A | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 80/218 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV64462708; called by muse, mutect2, varscan2
- BMP2 | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as COSV66578779; called by muse, mutect2, varscan2
- C12orf43 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 148/339 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs752827300, COSV56566492; called by muse, mutect2, varscan2
- CACNA2D4 | c.1532C>T p.A511V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54954279; called by muse, mutect2, varscan2
- CALB1 | c.315G>A p.K105= | Splice Region (SNP) | VAF 31/77 reads (40%) | catalogued as COSV55368620; called by muse, mutect2, varscan2
- CC2D2B | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369417630; called by muse, mutect2, varscan2
- CCR4 | c.345G>A p.W115* | Nonsense Mutation (SNP) | VAF 139/282 reads (49%) | catalogued as COSV58383106; called by muse, mutect2, varscan2
- CCT6B | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV58490625; called by muse, mutect2, varscan2
- CDC42BPG | c.4171C>T p.P1391S | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745688477, COSV100712171; called by muse, mutect2, varscan2
- CDH12 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66427735; called by muse, mutect2, varscan2
- CDHR2 | c.3080C>T p.S1027F | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); catalogued as COSV56136628; called by muse, mutect2, varscan2
- CES2 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57697253; called by muse, varscan2
- CFAP47 | c.4483G>A p.E1495K | Missense Mutation (SNP) | VAF 26/26 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.397); catalogued as COSV57975402; called by mutect2, varscan2
- CILP | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.257); catalogued as COSV56026397; called by muse, mutect2, varscan2
- CLEC4C | c.624G>A p.M208I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV63582992; called by mutect2, varscan2
- CNTN5 | c.2404C>T p.Q802* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV54336064; called by muse, mutect2
- CNTNAP4 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56686258, COSV56692256; called by muse, mutect2, varscan2
- CPAMD8 | c.450G>A p.W150* (on ENST00000651564; = p.W103* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV52230556, COSV52237430; called by muse, mutect2, varscan2
- CRCT1 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 23/36 reads (64%) | PolyPhen possibly damaging (0.477); catalogued as rs143986265; called by muse, varscan2
- CSMD1 | c.9125G>A p.G3042D (on ENST00000520002; = p.G3041D on NM_033225.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100154396; called by muse, mutect2, varscan2
- CTDSP1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV56090418; called by muse, mutect2, varscan2
- DNAH9 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 76/179 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52364140; called by muse, mutect2, varscan2
- EDDM3A | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs544246375, COSV58795372; called by mutect2, varscan2
- EVPL | c.4981G>A p.D1661N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV56911202; called by muse, mutect2, varscan2
- FBN1 | c.3193G>A p.E1065K | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as CD145750, COSV57324858; called by muse, mutect2, varscan2
- FGA | c.1504G>A p.G502S | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV57398701; called by muse, mutect2, varscan2
- GTDC1 | c.1153T>C p.C385R (on ENST00000344850 / NM_001354361.1; = p.C300R on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV54000885; called by muse, mutect2, varscan2
- HCN3 | c.1363G>C p.V455L | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as rs753739215, COSV61361924; called by muse, mutect2, varscan2
- HMGB4 | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV53937876, COSV99593134; called by muse, mutect2, varscan2
- KCNK1 | c.630G>A p.W210* | Nonsense Mutation (SNP) | VAF 80/130 reads (62%) | catalogued as COSV64035729; called by muse, varscan2
- LIX1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV57207694, COSV57207745; called by muse, varscan2
- LMAN1L | c.710C>T p.T237I | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as COSV59002819; called by muse, mutect2, varscan2
- LRP2 | c.12868G>A p.E4290K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.22); catalogued as COSV55543376; called by muse, mutect2, varscan2
- MCM4 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50627958; called by muse, mutect2, varscan2
- MEP1A | c.2132C>T p.A711V | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as rs1174784829, COSV57921637; called by muse, mutect2, varscan2
- MORC1 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV51726041; called by muse, mutect2, varscan2
- MUC16 | c.21725C>T p.S7242F | Missense Mutation (SNP) | VAF 69/166 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV67458459, COSV67472760; called by muse, mutect2, varscan2
- NCOR2 | c.1296G>T p.W432C | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62301218; called by mutect2, varscan2
- NEK5 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62881165; called by muse, mutect2, varscan2
- NPAS2 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV59560320; called by muse, mutect2, varscan2
- OR8I2 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1387354454, COSV100136187, COSV56169316; called by muse, mutect2, varscan2
- OTOL1 | c.101A>C p.K34T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV60007764; called by muse, mutect2, varscan2
- PCDH18 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61270542; called by muse, mutect2, varscan2
- PCDHGA6 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as COSV53993752; called by muse, mutect2, varscan2
- PCSK5 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as rs866965779, COSV65088298; called by muse, mutect2, varscan2
- PDE6B | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV55328808; called by muse, mutect2, varscan2
- PIK3C2G | c.4339G>A p.G1447R (on ENST00000676171; = p.G1406R on NM_004570.5) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV104383866, COSV56809737; called by muse, mutect2, varscan2
- PKDREJ | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.812); catalogued as rs1192409392, COSV53551256; called by muse, mutect2, varscan2
- PLCE1 | c.6064C>T p.P2022S | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as COSV53362255; called by muse, varscan2
- PLIN4 | c.2386G>A p.A796T (on ENST00000301286; = p.A811T on NM_001367868.2) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV100014271; called by muse, mutect2, varscan2
- PPP3R2 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100701524, COSV62456409; called by muse, mutect2, varscan2
- PRAME | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.274); catalogued as COSV67162172; called by muse, mutect2, varscan2
- PXK | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as rs1481243941, COSV57086220, COSV57087359, COSV57088863; called by muse, mutect2, varscan2
- PZP | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV54354474; called by muse, mutect2, varscan2
- RASGRP3 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as rs747302924, COSV67823734; called by muse, mutect2, varscan2
- RFPL4B | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as rs867306326, COSV71437288, COSV71437679; called by muse, mutect2, varscan2
- RFX6 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as rs1562149213, COSV60587357; called by muse, mutect2, varscan2
- RTP5 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV58321178; called by muse, mutect2, varscan2
- RYR2 | c.12241G>A p.E4081K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.61); PolyPhen benign (0.125); catalogued as rs763004638, COSV63685773; ClinVar: uncertain significance; called by mutect2, varscan2
- SEMA3E | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV57083673; called by muse, mutect2, varscan2
- SLC22A6 | c.1685G>A p.G562E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV100842947; called by muse, mutect2, varscan2
- SLCO6A1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs372939815; called by muse, mutect2, varscan2
- SNAP91 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV52119835, COSV52129120; called by muse, varscan2
- SNTG1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 46/137 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV52459237; called by muse, mutect2, varscan2
- STK36 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV55308663; called by mutect2, varscan2
- TRIM26 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.992); catalogued as COSV70983298; called by muse, varscan2
- TTN | c.3655G>A p.E1219K (on ENST00000591111; = p.E1173K on NM_003319.4) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | PolyPhen possibly damaging (0.831); catalogued as COSV60148522; called by mutect2, varscan2
- VN1R2 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59039071; called by muse, mutect2, varscan2
- WNK2 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52951872; called by muse, mutect2, varscan2
- YIPF7 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.069); catalogued as rs747871587, COSV60657521; called by muse, mutect2, varscan2
- ZFHX4 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.116); catalogued as COSV50656806; called by muse, mutect2, varscan2
- ZNF385D | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748061594, COSV55766451; called by muse, mutect2, varscan2
- FAM90A1 | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.636); called by mutect2, varscan2
- ACSM1 | c.756G>A p.R252= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV54638311; called by muse, mutect2, varscan2
- ATRX | c.4155G>A p.Q1385= | Silent (SNP) | VAF 53/56 reads (95%) | catalogued as COSV64880485; called by muse, mutect2, varscan2
- BAG6 | c.1818G>A p.P606= (on ENST00000676571; = p.P559= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/220 reads (21%) | catalogued as rs766003428, COSV99277701; called by mutect2, varscan2
- BAHCC1 | c.2859G>A p.L953= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV57030599; called by muse, mutect2, varscan2
- BAZ2A | c.4638C>T p.T1546= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs983148298, COSV51640532; called by muse, mutect2, varscan2
- CCDC148 | c.1482G>A p.R494= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV51766507; called by muse, mutect2, varscan2
- CDK6 | c.417C>T p.H139= | Silent (SNP) | VAF 108/198 reads (55%) | catalogued as rs750209850, COSV56010856, COSV56014189, COSV56015223; called by muse, mutect2, varscan2
- CHRNA5 | c.1266C>T p.F422= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as rs1368710972, COSV55138415; called by mutect2, varscan2
- CTSD | c.1125C>T p.I375= | Silent (SNP) | VAF 33/58 reads (57%) | catalogued as COSV52589291; called by muse, mutect2, varscan2
- CYP8B1 | c.150G>A p.R50= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV60227115; called by muse, mutect2, varscan2
- DNAH5 | c.6753G>A p.T2251= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as rs571519805, COSV54203142; called by muse, mutect2, varscan2
- DPP10 | c.1014C>T p.N338= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV59706265; called by muse, mutect2, varscan2
- EVPL | c.4980G>A p.R1660= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs760779253, COSV101440982; called by muse, mutect2, varscan2
- GBP1 | c.757C>T p.L253= | Silent (SNP) | VAF 97/216 reads (45%) | catalogued as rs370041200; called by muse, mutect2, varscan2
- HYDIN | c.9378G>A p.K3126= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs1567778512, COSV59264307; called by muse, mutect2, varscan2
- KCNH7 | c.1243C>T p.L415= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV59806064; called by muse, mutect2, varscan2
- KCNQ1 | c.1959C>T p.F653= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as COSV50116772; called by muse, mutect2, varscan2
- KIF21A | c.684C>T p.A228= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV62768021; called by muse, mutect2, varscan2
- KIF5C | c.795G>A p.V265= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV101276217; called by mutect2, varscan2
- LY86 | c.129G>A p.Q43= | Silent (SNP) | VAF 17/90 reads (19%) | catalogued as COSV100040969, COSV57913265; called by muse, mutect2, varscan2
- MYH1 | c.1602C>T p.F534= | Silent (SNP) | VAF 46/97 reads (47%) | catalogued as rs202088665, COSV56853339, COSV99876732; called by muse, mutect2, varscan2
- NRK | c.2676C>T p.G892= | Silent (SNP) | VAF 70/79 reads (89%) | catalogued as rs774141954, COSV54602146; called by muse, mutect2, varscan2
- OR1F1 | c.339C>T p.F113= | Silent (SNP) | VAF 79/173 reads (46%) | catalogued as COSV58960406; called by muse, mutect2, varscan2
- OR51A2 | c.262C>T p.L88= | Silent (SNP) | VAF 52/58 reads (90%) | catalogued as rs1425087614, COSV66748612; called by muse, varscan2
- OR6C1 | c.938G>A p.*313= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV101110569, COSV65572992; called by mutect2, varscan2
- PHYKPL | c.744C>T p.I248= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV57425403, COSV57426895; called by muse, varscan2
- PLIN4 | c.2385G>A p.V795= (on ENST00000301286; = p.V810= on NM_001367868.2) | Silent (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100014276; called by mutect2, varscan2
- PPIC | c.336C>T p.I112= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1215077450, COSV60575006; called by muse, mutect2, varscan2
- RCAN1 | c.348C>T p.P116= | Silent (SNP) | VAF 309/351 reads (88%) | catalogued as rs760312297, COSV58251030; called by muse, mutect2, varscan2
- SLC16A7 | c.108C>T p.F36= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV53897544; called by muse, mutect2, varscan2
- SLC46A3 | c.1150C>T p.L384= | Silent (SNP) | VAF 60/128 reads (47%) | catalogued as rs774371786, COSV57183301; called by muse, mutect2, varscan2
- SLC66A2 | c.549C>T p.A183= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as COSV60844165; called by muse, mutect2, varscan2
- UGT3A1 | c.1386C>T p.I462= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV57100765; called by muse, mutect2, varscan2
- ZADH2 | c.315G>A p.V105= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as COSV59269256; called by muse, mutect2, varscan2
- ZNF468 | c.669C>T p.S223= | Silent (SNP) | VAF 38/73 reads (52%) | catalogued as COSV54693287, COSV54696063; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7792C>T | Intron (SNP) | VAF 20/22 reads (91%) | catalogued as rs752059083, COSV100875752, COSV63390102; called by mutect2, varscan2
- OR2W5 | n.318G>A | RNA (SNP) | VAF 76/132 reads (58%) | catalogued as rs979035329; called by muse, mutect2, varscan2
- ZNF99 | c.*771A>G | 3'UTR (SNP) | VAF 18/39 reads (46%) | catalogued as COSV101233990; called by muse, mutect2, varscan2
